Gene-level copy-number profile of tumor specimen TCGA-V4-A9EU-01A from TCGA case TCGA-V4-A9EU, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Ciliary body; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 83.3 years (30,409 days).
Specimen TCGA-V4-A9EU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.5a19da15-0e88-4cd2-87b1-1042393c0baf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V4-A9EU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/893997c2-8017-4b93-b44e-105268c1c1b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,241; copy number 2: 45,322; copy number 3: 2,718; copy number 6: 214; copy number 7: 1,320.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V4-A9EU-01A-11D-A39V-01): tumor purity 0.97, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,534 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 6–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,820. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
